Somatic mutation profile of tumor specimen MMRF_1781_1_BM_CD138pos (aliquot MMRF_1781_1_BM_CD138pos_T1_KBS5U_L06441) from MMRF case MMRF_1781, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.4 years (25,345 days).
Specimen MMRF_1781_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84259d51-64dc-4b61-9fdc-f2e5067fe924.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1781_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1781_1_PB_Whole_C2_KBS5U_L06490; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e1aaa7b-7f53-40d8-8077-88a671556ed9

The open-access MAF lists 121 somatic variants for this specimen: 40 protein-altering or splice-affecting, 17 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 36, Missense Mutation 33, Silent 17, Intron 11, 5'UTR 8, RNA 4, Nonsense Mutation 3, 5'Flank 3, 3'Flank 2, Splice Site 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD44 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.133); catalogued as COSV99555494; called by muse, mutect2, varscan2
- IGHV2-70 | c.290A>C p.N97T | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs769646259; called by muse, varscan2
- IGHV2-70 | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs549292393; called by muse, varscan2
- IGLV3-1 | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs61731694; called by muse, varscan2
- KCTD2 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV100483197; called by muse, mutect2, varscan2
- KRT79 | c.1486dup p.A496Gfs*13 | Frame Shift Ins (INS) | VAF 57/155 reads (37%) | catalogued as rs746321620; called by mutect2, varscan2
- MARVELD3 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 27/28 reads (96%) | catalogued as rs768257715, COSV51703984, COSV51704500; called by muse, mutect2, varscan2
- MASP2 | c.1654T>C p.C552R | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs112256324; called by muse, mutect2, varscan2
- MS4A1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 127/275 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs1313395216, COSV100619394; called by muse, mutect2, varscan2
- MUC5B | c.15109G>A p.V5037I | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs200849036; called by muse, mutect2, varscan2
- TMC3 | c.1015T>G p.F339V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV63923461; called by muse, mutect2, varscan2
- UGT8 | c.1053G>C p.K351N | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as COSV60422070; called by muse, mutect2, varscan2
- ZIC1 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 134/173 reads (77%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.883); catalogued as rs759538522; called by muse, mutect2, varscan2
- ZNF780B | c.1730G>A p.S577N | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as rs956147030; called by muse, mutect2
- ABCB1 | c.1644C>A p.N548K | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ALMS1 | c.3136C>T p.Q1046* | Nonsense Mutation (SNP) | VAF 12/330 reads (4%) | called by muse, mutect2
- APC | c.7733C>T p.S2578L | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- APOB | c.5335T>G p.F1779V | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- CNOT2 | c.1595A>G p.N532S | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- DENND3 | c.3459C>G p.D1153E | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- DIAPH3 | c.2019T>A p.Y673* (on ENST00000400324 / NM_001042517.2; = p.Y410* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- EEFSEC | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 127/249 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATA4 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 96/115 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KDM5C | c.408_409del p.V137Sfs*28 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- KRT81 | c.985A>T p.I329F | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- LHX6 | c.625C>T p.P209S (on ENST00000373755 / NM_001242334.2; = p.P238S on NM_014368.5) | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- LRIT3 | c.1267A>G p.T423A | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAMSTR | c.550C>G p.L184V (on ENST00000318083 / NM_001130915.2; = p.L81V on NM_182574.2) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEF2D | c.608-2A>T p.X203_splice | Splice Site (SNP) | VAF 39/172 reads (23%) | called by muse, mutect2, varscan2
- MUC19 | n.5105G>A | Splice Region (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- OBSCN | c.22319G>A p.G7440E | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52J3 | c.80T>C p.M27T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPFIA2 | c.2450G>T p.S817I | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PPFIA4 | c.2278C>A p.L760M (on ENST00000447715; = p.L761M on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2
- PTPN14 | c.40A>C p.N14H | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- RARS2 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.14836G>A p.E4946K | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); called by muse, mutect2
- SLC25A35 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STAB1 | c.5795A>G p.H1932R | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF695 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ADGRL3 | c.3807C>T p.L1269= (on ENST00000506720 / NM_001322402.2; = p.L1201= on NM_015236.6) | Silent (SNP) | VAF 49/112 reads (44%) | called by muse, mutect2, varscan2
- BID | c.42G>A p.A14= | Silent (SNP) | VAF 73/171 reads (43%) | called by muse, mutect2, varscan2
- BRINP3 | c.1434C>T p.V478= | Silent (SNP) | VAF 79/271 reads (29%) | catalogued as COSV66536903; called by muse, mutect2, varscan2
- BTBD16 | c.1152G>T p.L384= | Silent (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- CDH22 | c.1815C>A p.S605= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV64837283; called by muse, mutect2, varscan2
- COL15A1 | c.3576T>G p.P1192= | Silent (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- COL6A3 | c.4260A>G p.L1420= | Silent (SNP) | VAF 9/212 reads (4%) | called by muse, mutect2
- EID2 | c.651T>A p.S217= | Silent (SNP) | VAF 14/490 reads (3%) | called by muse, mutect2
- FTCD | c.228C>T p.S76= | Silent (SNP) | VAF 43/64 reads (67%) | called by muse, mutect2, varscan2
- HS3ST5 | c.316C>T p.L106= | Silent (SNP) | VAF 61/185 reads (33%) | catalogued as COSV57134770; called by muse, mutect2, varscan2
- IGKV4-1 | c.192G>A p.Q64= | Silent (SNP) | VAF 93/96 reads (97%) | catalogued as rs374170740; called by muse, mutect2, varscan2
- IGKV4-1 | c.285A>C p.T95= | Silent (SNP) | VAF 75/77 reads (97%) | called by muse, mutect2, varscan2
- IGLL5 | c.195C>T p.S65= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as rs151173231, COSV104440338, COSV73251128; called by muse, mutect2, varscan2
- NPFFR2 | c.957G>A p.K319= | Silent (SNP) | VAF 74/151 reads (49%) | catalogued as COSV58154452; called by muse, mutect2, varscan2
- SLC4A4 | c.315C>T p.P105= (on ENST00000264485 / NM_001098484.3; = p.P61= on NM_003759.4) | Silent (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- TP53I11 | c.204C>G p.V68= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- TRAPPC11 | c.3018C>T p.H1006= | Silent (SNP) | VAF 52/123 reads (42%) | catalogued as rs149934183; called by muse, mutect2, varscan2
- AC078880.2 | n.681C>T | RNA (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- AGAP1 | c.*1971G>A | 3'UTR (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- ARL4A | chr7:12689538 A>G | 3'Flank (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- B3GALNT1 | c.-221+113G>A | Intron (SNP) | VAF 25/236 reads (11%) | called by muse, mutect2, varscan2
- BCL11A | c.*1081A>T | 3'UTR (SNP) | VAF 61/109 reads (56%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>T | 5'Flank (SNP) | VAF 42/99 reads (42%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- C2orf91 | n.2667C>A | RNA (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- CCNT2 | c.*3008G>A | 3'UTR (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- CLDND1 | c.*874G>A | 3'UTR (SNP) | VAF 148/538 reads (28%) | called by muse, mutect2, varscan2
- CLVS1 | c.*897_*898insGAAG | 3'UTR (INS) | VAF 7/55 reads (13%) | called by mutect2, pindel
- COL4A3 | c.1409-128C>T | Intron (SNP) | VAF 26/45 reads (58%) | catalogued as rs545613079; called by muse, mutect2, varscan2
- CRNKL1 | c.*1070T>C | 3'UTR (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.124-30T>A | Intron (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- CXXC1 | c.-361T>A | 5'UTR (SNP) | VAF 14/81 reads (17%) | catalogued as rs1242115686; called by muse, mutect2, varscan2
- CYS1 | c.*1224T>C | 3'UTR (SNP) | VAF 92/161 reads (57%) | catalogued as rs1355808704; called by muse, mutect2, varscan2
- CYTH2 | c.*162_*165del | 3'UTR (DEL) | VAF 18/76 reads (24%) | catalogued as rs1289390751; called by pindel, varscan2
- DAAM1 | c.*745dup | 3'UTR (INS) | VAF 26/35 reads (74%) | catalogued as rs1312944382; called by mutect2, varscan2
- DARS2 | c.-181G>A | 5'UTR (SNP) | VAF 38/168 reads (23%) | called by muse, mutect2, varscan2
- DBF4B | c.1190-930C>T | Intron (SNP) | VAF 25/45 reads (56%) | catalogued as rs1222583814; called by muse, mutect2, varscan2
- DTX1 | c.-355C>T | 5'UTR (SNP) | VAF 26/65 reads (40%) | catalogued as COSV104379953; called by muse, mutect2, varscan2
- DUS2 | c.-19+600T>C | Intron (SNP) | VAF 8/8 reads (100%) | called by muse, mutect2, varscan2
- EDRF1 | c.3277+72G>T | Intron (SNP) | VAF 14/35 reads (40%) | catalogued as rs751101076; called by muse, mutect2
- EIF3E | c.91-16T>G | Intron (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- ELOVL1 | c.*214C>T | 3'UTR (SNP) | VAF 27/62 reads (44%) | catalogued as rs879544992; called by muse, mutect2, varscan2
- FAM131A | chr3:184346382 G>A | 3'Flank (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- FAM207A | chr21:44939926 C>A | 5'Flank (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2, varscan2
- FEN1 | c.*220C>T | 3'UTR (SNP) | VAF 146/320 reads (46%) | called by muse, mutect2, varscan2
- G3BP1 | c.443-111T>C | Intron (SNP) | VAF 6/31 reads (19%) | catalogued as rs1561535760; called by muse, mutect2
- GAPT | c.*662T>G | 3'UTR (SNP) | VAF 52/107 reads (49%) | called by muse, mutect2, varscan2
- GMNC | c.*383C>A | 3'UTR (SNP) | VAF 37/190 reads (19%) | called by muse, mutect2, varscan2
- GPAT4 | c.*762G>T | 3'UTR (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- GPAT4 | c.*878G>T | 3'UTR (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- GTF2A1 | c.-151T>A | 5'UTR (SNP) | VAF 51/59 reads (86%) | called by muse, mutect2, varscan2
- HMGA2 | c.*1007_*1009del | 3'UTR (DEL) | VAF 4/33 reads (12%) | catalogued as rs971169177; called by pindel, varscan2
- KCNJ3 | c.*1287G>A | 3'UTR (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- KLHL23 | c.*318C>T | 3'UTR (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2
- KLHL24 | c.1602+157G>C | Intron (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- MFAP3L | c.*412G>A | 3'UTR (SNP) | VAF 55/116 reads (47%) | called by muse, mutect2, varscan2
- MYO3A | c.*237C>A | 3'UTR (SNP) | VAF 112/278 reads (40%) | called by muse, mutect2, varscan2
- NGEF | c.*40G>C | 3'UTR (SNP) | VAF 23/63 reads (37%) | catalogued as COSV99889473; called by muse, mutect2, varscan2
- OBSCN | c.11660-2845C>T | Intron (SNP) | VAF 26/62 reads (42%) | catalogued as rs975607869; called by muse, mutect2, varscan2
- OR2Y1 | c.*58C>T | 3'UTR (SNP) | VAF 17/494 reads (3%) | called by muse, mutect2
- PCYOX1L | c.*193G>A | 3'UTR (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- PHC1 | c.*661C>A | 3'UTR (SNP) | VAF 13/52 reads (25%) | called by mutect2, varscan2
- POFUT1 | c.*693G>T | 3'UTR (SNP) | VAF 53/132 reads (40%) | called by muse, mutect2, varscan2
- QPCT | c.*332T>G | 3'UTR (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- RYR2 | c.*328C>A | 3'UTR (SNP) | VAF 133/216 reads (62%) | called by muse, mutect2, varscan2
- RYR2 | c.*936A>G | 3'UTR (SNP) | VAF 77/145 reads (53%) | called by muse, mutect2, varscan2
- SGSM2 | c.1507+29G>T | Intron (SNP) | VAF 35/63 reads (56%) | called by muse, mutect2, varscan2
- SH3RF3 | c.*2835C>T | 3'UTR (SNP) | VAF 52/122 reads (43%) | called by mutect2, varscan2
- SLITRK5 | c.*958T>A | 3'UTR (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- SURF4 | c.*1675G>A | 3'UTR (SNP) | VAF 42/100 reads (42%) | catalogued as rs913667296; called by muse, mutect2, varscan2
- TBC1D29P | n.2929A>T | RNA (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- TBCEL | c.*3451T>C | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2
- TBCEL | c.*3453T>C | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2
- TDGF1P3 | n.840C>T | RNA (SNP) | VAF 74/91 reads (81%) | catalogued as rs1289880179; called by muse, mutect2, varscan2
- TMED3 | c.-105G>A | 5'UTR (SNP) | VAF 6/9 reads (67%) | catalogued as rs1465111241; called by muse, mutect2, varscan2
- TMEM245 | c.-3A>G | 5'UTR (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- UBE2K | chr4:39698132 C>A | 5'Flank (SNP) | VAF 36/70 reads (51%) | catalogued as rs949098503; called by muse, varscan2
- UBE2K | c.-118T>C | 5'UTR (SNP) | VAF 47/99 reads (47%) | called by muse, varscan2
- USP6NL | c.*1022T>C | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- VAMP2 | c.*938T>A | 3'UTR (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- VPS18 | c.-276G>C | 5'UTR (SNP) | VAF 12/149 reads (8%) | called by muse, mutect2
- WDR5B | c.*2174C>A | 3'UTR (SNP) | VAF 63/123 reads (51%) | called by muse, mutect2, varscan2
